MMRF case MMRF_1929 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6033a5b8-684f-4951-a87e-ebafb69822bc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.6 years (22,872 days); ISS stage: II; Days to last known disease status: 1,000 days (2.7 years); Days to last follow up: 1,000 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 111 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 3.1 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 6.31 ×10⁹/L; Absolute Neutrophil 3.22 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 5.45 mmol/L.
- Day 85: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Hemoglobin 6.57 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.03 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.05 mmol/L; Albumin 29 g/L; Total Protein 5.9 g/dL; Glucose 4.4 mmol/L.
- Day 160 (ECOG 0): Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.73 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.05 mmol/L; Albumin 27 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.
- Day 288 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.757 mg/dL; Immunoglobulin G 5.19 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.44 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 355 (ECOG 0): Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.36 ×10⁹/L; Absolute Neutrophil 1.17 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.33 mmol/L.
- Day 456 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.82 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.28 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 28.6 mmol/L; Calcium 2.05 mmol/L; Albumin 31 g/L; Total Protein 6 g/dL; Glucose 4.4 mmol/L.
- Day 540 (ECOG 0): Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.67 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 631 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.02 ×10⁹/L; Absolute Neutrophil 0.94 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 4.62 mmol/L.
- Day 733 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 817: Hemoglobin 7.38 mmol/L; Leukocytes 3.61 ×10⁹/L; Absolute Neutrophil 1.64 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 6.27 mmol/L.
- Day 902: Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.94 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 5.9 g/dL; Glucose 5.34 mmol/L.
- Day 1,000: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.757 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.29 ×10⁹/L; Absolute Neutrophil 0.86 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -1: Weight: 54 kg; Height: 150 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1929_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1929_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
